Surgical pathology report (de-identified scan), TCGA case TCGA-49-AARN, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AARN-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, RIGHT LOWER LOBE (RIGHT LOWER LOBECTOMY): INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (2.2 CM). THE NEOPLASM DOES NOT INVADE INTO THE PLEURA. NO VASCULAR INVASION IS IDENTIFIED. ALL SURGICAL MARGINS ARE NEGATIVE FOR TUMOR. THE PATHOLOGIC STAGE IS T1N0MX.

2. LYMPH NODE, LEVEL 7 (BX.): TWO (2) LYMPH NODES AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

3. LYMPH NODE, 4R (BX): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

NOTE: Immunohistochemical studies confirm the primary lung origin of this tumor. Specifically, the tumor cells are immunoreactive for TTF-1; and they are non-immunoreactive for estrogen receptor, progesterone receptor and gross cystic disease fluid protein.

*Electronic signature

=====

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3

Adenocarcinoma NOS 8140/3

Site @ Lung, lower lobe C34.3

JY 5/20/14

[page 2 of 3]
PART #1: RIGHT LUNG
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated right lung. It consists of a lobe of lung weighing 260 gms, and measuring 13 x 13 x 3 cm. On sectioning, externally, the tumor is located peripherally, with distinct pleura puckering. The tumor is grossly away from the bronchial and vascular margin (greater than 2 cm). The bronchial and vascular margins are shaved off. There is a stapled margin approximately 1.5 cm in length which is shaved and a portion placed in cassette C. Upon sectioning gross tumor is identified. The tumor is located peripherally, the tumor measures 2.2 x 2 x 1.8 cm. The tumor appears discrete, solid, and firm, tan-gray in color. The surrounding pleura parenchyma does not seem to be involved by the tumor. There is distinct pleura puckering on the surface. The bronchial segments are opened from the bronchial margin towards the tumor and grossly no tumor involvement is identified. Vascular vessels of the specimen are also opened with no grossly identifiable tumor. The tumor grossly does not penetrate the visceral pleura. The distance of tumor from the bronchial margin of resection is greater than 2 cm. The origin of the tumor from the bronchus is not identified. The non-neoplastic lung appears to be closely unremarkable. Dissection of the hilar area, reveals no lymph nodes. Sections of the hilar region as well as normal non-neoplastic lung are submitted. Frozen section are not taken. A small portion of the tumor is submitted for tumor bank, along with normal tissue from the specimen.

SUMMARY OF SECTIONS:

1	- A	- 1	(BRONCHIAL MARGIN)
1	- B	- 3	(VASCULAR MARGIN)
1	- C	- 2	(STAPLED MARGIN)
1	-D-G	- 1	EA. (TUMOR SECTIONS)
1	- H	- 1	(NORMAL LUNG)
1	- I	- 1	(HILAR AREA)
9	- TOTAL	- 12	

(Continued on next page.)

[page 3 of 3]
PART #2: LEVEL 7
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated level 7. It consists of a single piece of fibroadipose tissue grossly consistent with a portion of lymph node. The total surface is anthracotic and measures 1.2 x 0.6 x 0.2 cm. The specimen is bivalved and submitted.

SUMMARY OF SECTIONS:

1 - A - 2
1 - TOTAL - 2

PART #3: 4 R
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated 4-R. It consists of a single piece of fibroadipose tissue grossly consistent with a lymph node measuring 1 x 0.5 x 0.2 cm. The specimen is bivalved and submitted in its entirety.

SUMMARY OF SECTIONS:

1 - A - 2
1 - TOTAL - 2

(End of Report)

printed

Criteria	1/18/14	Yes	No

Source: NCI Genomic Data Commons file b12d95fb-56df-4208-9cd0-63dedd8ae50d (TCGA-49-AARN.19256999-CAE3-4D04-AA1C-758B4E80BCD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).